Somatic mutation profile of tumor specimen TARGET-20-PASMTK-09A (aliquot TARGET-20-PASMTK-09A-01D) from TARGET case TARGET-20-PASMTK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,179 days).
Specimen TARGET-20-PASMTK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 623d2788-fe1c-48be-8dfe-6020d85e84e3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMTK-14A (Bone Marrow Normal), aliquot TARGET-20-PASMTK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc4f45a-31cd-4f3d-9402-79c1a5a7e5f2

The open-access MAF lists 26 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 7, Silent 6, Missense Mutation 5, Frame Shift Ins 2, Intron 2, Splice Site 1, Nonstop Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGBP | c.6523G>A p.A2175T | Missense Mutation (SNP) | VAF 92/401 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.137); catalogued as rs531389886; called by muse, mutect2, varscan2
- JMJD1C | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs192996860, COSV101232365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRUNE2 | c.5960T>C p.V1987A | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs544336657; called by muse, mutect2, varscan2
- RUNX1 | c.512A>G p.D171G (on ENST00000344691 / NM_001001890.3; = p.D198G on NM_001754.5) | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55867088, COSV55868325; called by muse, mutect2, varscan2
- SUPT5H | c.2273C>A p.P758Q | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs530828946; called by muse, mutect2, varscan2
- DGCR8 | c.2183dup p.N728Kfs*17 | Frame Shift Ins (INS) | VAF 9/97 reads (9%) | called by pindel, varscan2
- GATA2 | c.724dup p.T242Nfs*40 | Frame Shift Ins (INS) | VAF 45/93 reads (48%) | called by mutect2, pindel, varscan2
- LAMA1 | c.3387del p.C1129* | Frame Shift Del (DEL) | VAF 45/113 reads (40%) | called by mutect2, pindel, varscan2
- NUP205 | c.6037T>C p.*2013Rext*21 | Nonstop Mutation (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- TET2 | c.4044+3_4044+7dup p.X1348_splice | Splice Site (INS) | VAF 57/133 reads (43%) | called by mutect2, pindel, varscan2
- ADCY5 | c.1095C>A p.A365= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1282007524; called by muse, mutect2, varscan2
- ARID1B | c.2685A>G p.P895= | Silent (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- HOXB3 | c.861G>A p.E287= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs564050901; called by muse, mutect2, varscan2
- NOS1 | c.819C>T p.V273= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs369890513; ClinVar: likely benign; called by muse, mutect2, varscan2
- TJP3 | c.2745G>A p.P915= | Silent (SNP) | VAF 68/145 reads (47%) | catalogued as rs748842822; called by muse, mutect2
- TNC | c.1818G>A p.S606= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as rs559423461; called by muse, mutect2, varscan2
- AFF3 | c.*1890del | 3'UTR (DEL) | VAF 33/98 reads (34%) | catalogued as rs772949506; called by mutect2, varscan2
- AHNAK | c.-79C>T | 5'UTR (SNP) | VAF 46/89 reads (52%) | catalogued as rs535535772; called by muse, mutect2, varscan2
- CUL9 | c.6847-30C>A | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- DGCR8 | c.*1270_*1271insTC | 3'UTR (INS) | VAF 56/220 reads (25%) | catalogued as rs3081766, COSV52813103; called by pindel, varscan2
- FHDC1 | c.*2869_*2870del | 3'UTR (DEL) | VAF 82/205 reads (40%) | called by mutect2, pindel, varscan2
- LPP | c.*13067G>T | 3'UTR (SNP) | VAF 130/270 reads (48%) | catalogued as rs370554214; called by muse, mutect2, varscan2
- PTBP1 | c.39+31C>A | Intron (SNP) | VAF 75/162 reads (46%) | catalogued as rs550976488, COSV62460694; called by muse, mutect2, varscan2
- RUNX1 | c.*3373G>A | 3'UTR (SNP) | VAF 86/150 reads (57%) | catalogued as rs768835446; called by muse, mutect2, varscan2
- STAT6 | c.*660T>C | 3'UTR (SNP) | VAF 129/268 reads (48%) | called by muse, mutect2, varscan2
- TSC22D1 | c.*1596A>G | 3'UTR (SNP) | VAF 120/245 reads (49%) | catalogued as rs929285595; called by muse, mutect2, varscan2
